CCDI case PBBSAE — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/e6187762-d243-48c0-899e-23154ee19c91

Demographics
Sex at birth: female.

Diagnoses (1)
1. Astrocytoma, NOS: ICD-O-3 morphology code: 9400/3; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 16.7 years (6,100 days).

Biospecimens (3 samples)
- Sample 0DFJJ2: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DFJKC: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DFJKS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
